CCDI case PBBUAY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2606d263-1e1f-4c16-90a2-32bb2bef3068

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.0 years (1,099 days).

Biospecimens (3 samples)
- Sample 0DH27H: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DH28T: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DH29M: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
